Gene-level copy-number profile of tumor specimen TCGA-63-A5MH-01A from TCGA case TCGA-63-A5MH, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IA.
Specimen TCGA-63-A5MH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.88ad69e5-1e7f-4cc5-8e3a-4dcba2b0c0dd.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-63-A5MH-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/65b52822-2327-4b9f-a0c2-ce3418d85a0b

Most common (modal) total copy number across autosomal genes: 1 — below the diploid value of 2.
Genes by total copy number (all chromosomes): copy number 0: 75; copy number 1: 31,626; copy number 2: 24,926; copy number 3: 2,469; copy number 4: 724.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-63-A5MH-01A-12D-A27J-01): tumor purity 0.91, ploidy 1.51, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 75 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:157,876,702–158,753,775, 17 genes: UPP2, AC013731.1, RNU6-436P, AC091488.1, MTA3P1, RNU6-932P, PTP4A1P1, UPP2-IT1, CCDC148-AS1, CCDC148, HNRNPDLP2, RN7SL393P, PKP4, RPL7AP22, PKP4-AS1, AC005042.1, AC005042.2.
- chr2:187,001,876–189,225,312, 22 genes: IMPDH1P7, AC007319.1, RN7SKP42, RNU6-989P, CALCRL, GAPDHP59, TFPI, LINC01090, ST13P2, AC104131.1, RNA5SP114, GULP1, MIR561, AC092598.1, DIRC1, COL3A1, MIR1245A, MIR1245B, MIR3606, COL5A2, AC133106.1, MIR3129.
- chr2:190,992,639–191,425,389, 11 genes: RAB1AP1, AC067945.1, AC067945.2, STAT4, AC067945.3, RNU6-959P, AC079777.1, HMGB1P27, AC092614.1, MYO1B, RNU6-1045P.
- chr2:191,682,452–191,682,633, 1 gene: AC114778.1.
- chr2:201,182,898–201,480,846, 10 genes (within-gene range 0–1): CASP10, MTND5P25, MTND4P23, MTND4LP13, CASP8, FLACC1, TRAK2, STRADB, SCYL2P1, Y_RNA.
- chr3:77,567,508–78,294,731, 7 genes: AC133040.1, RNU6-217P, LINC02077, AC117462.1, RN7SL647P, RN7SKP61, AC108752.1.
- chr5:89,900,664–89,990,883, 1 gene: AC113167.1.
- chr14:102,777,449–103,057,549, 6 genes (within-gene range 0–1): TRAF3, RNU6-1316P, AMN, CDC42BPB, AL117209.1, RPL13P6.

Amplified relative to the modal value (total copy number ≥ 3, i.e. more than twice the modal value of 1; autosomes only): 3,193 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:57,598–2,413,797, 154 genes, copy number 3 (broad region; genes not listed).
- chr1:143,343,180–155,689,000, 567 genes, copy number 3 (within-gene range 2–3) (broad region; genes not listed).
- chr3:98,233,651–98,457,898, 1 gene, copy number 3 (within-gene range 2–3): AC117473.1.
- chr3:98,306,752–198,222,513, 1,747 genes, copy number 3 (broad region; genes not listed).
- chr4:128,061,286–129,116,640, 14 genes, copy number 4: LARP1B, AC099340.1, FOSL1P1, PGRMC2, LINC02615, AC110609.1, AC078850.1, AC078850.2, JADRR, JADE1, SCLT1, AC093783.1, AC093826.1, C4orf33.
- chr5:58,198–45,895,970, 710 genes, copy number 4 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 29,245. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
